Gene-level copy-number profile of tumor specimen TCGA-ZF-A9RF-01A from TCGA case TCGA-ZF-A9RF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.7 years (27,281 days).
Specimen TCGA-ZF-A9RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0280ebd8-d7ff-4097-bc17-ca5722e0c9bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-A9RF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6823814-7ed9-4fd2-a441-0a26d0d2e7f6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 1,418; copy number 2: 18,236; copy number 3: 23,280; copy number 4: 7,751; copy number 5: 4,992; copy number 6: 2,043; copy number 7: 1,214; copy number 8: 342; copy number 9: 92; copy number 11: 43; copy number 12: 251; copy number 13: 10; copy number 15: 7; copy number 16: 8; copy number 17: 62; copy number 24: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-A9RF-01A-11D-A38F-01): tumor purity 0.5, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,208,193–83,437,728, 14 genes: AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, AC023503.1.
- chr4:90,127,535–91,601,913, 6 genes (within-gene range 0–2): CCSER1, RN7SKP248, AC093729.1, TMSB4XP8, AC004054.1, AC074124.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,064 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–163,355,764, 882 genes, copy number 7 (broad region; genes not listed).
- chr1:165,201,867–170,588,236, 132 genes, copy number 7 (broad region; genes not listed).
- chr3:84,958,989–90,261,708, 43 genes, copy number 16–24 (within-gene range 1–24): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:55,346,242–57,207,459, 54 genes, copy number 7: SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1.
- chr4:61,906,313–62,292,337, 6 genes, copy number 9: Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1.
- chr4:71,062,667–71,572,087, 2 genes, copy number 8–9 (within-gene range 3–13): SLC4A4, AC096713.1.
- chr4:104,230,380–123,403,760, 270 genes, copy number 8–12 (broad region; genes not listed).
- chr4:130,881,027–134,010,690, 26 genes, copy number 7 (within-gene range 1–7): AC093831.1, AC093902.1, AC025554.1, RNU6-224P, LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2, AC093916.1, AC096711.1, ELL2P2, AC114741.1, LINC01256, AARS1P1, AC115622.1, AC110751.1, AC105383.1, R3HDM2P1, PCDH10, AC108052.1, AC105252.1, AC079380.1.
- chr4:134,327,063–148,444,698, 197 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr6:78,604,467–82,367,420, 58 genes, copy number 8: AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2, LINC01621, AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK, AL591135.2, AL591135.1, AK4P5, BCKDHB, AL359715.3, RPL17P25, AL359715.4, AL359715.1, AL359715.2, RPSAP72, AL596028.1, AL590824.1, TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1, IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG.
- chr8:31,639,222–32,855,666, 1 gene, copy number 15 (within-gene range 2–15): NRG1.
- chr8:32,026,210–32,911,598, 6 genes, copy number 15: NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P.
- chr8:35,672,195–36,321,404, 10 genes, copy number 13: AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:41,653,220–41,896,762, 1 gene, copy number 11 (within-gene range 5–11): ANK1.
- chr8:41,803,349–43,544,057, 58 genes, copy number 9–11: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2.
- chr8:122,781,655–122,974,510, 1 gene, copy number 7 (within-gene range 5–7): ZHX2.
- chr8:122,977,026–123,416,350, 24 genes, copy number 7: AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, AC068228.3, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6.
- chr11:42,939,775–42,939,998, 1 gene, copy number 8: AC109810.1.
- chr12:50,392,383–51,028,566, 18 genes, copy number 7 (within-gene range 3–7): LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2.
- chr16:6,873,899–8,532,013, 14 genes, copy number 7–8: RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2.
- chr16:18,570,448–21,520,444, 84 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr16:24,472,798–26,137,685, 31 genes, copy number 9–11 (within-gene range 2–11): AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16.
- chr19:29,205,320–33,225,850, 83 genes, copy number 12–17 (broad region; genes not listed).
- chr20:43,423,196–45,233,331, 62 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
